Somatic mutation profile of tumor specimen TCGA-14-0740-01B (aliquot TCGA-14-0740-01B-01D-1845-08) from TCGA case TCGA-14-0740, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 70.2 years (25,627 days).
Specimen TCGA-14-0740-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d8f8405-f330-494f-b74e-1d0e20106269.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-0740-10B (Blood Derived Normal), aliquot TCGA-14-0740-10B-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e454eca-1765-45b7-be47-89ed656717ee

The open-access MAF lists 51 somatic variants for this specimen: 36 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 12, Nonsense Mutation 3, RNA 2, Splice Site 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 103/109 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.5724G>C p.Q1908H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV66067724; called by muse, mutect2, varscan2
- AL162417.1 | c.185C>A p.A62D | Missense Mutation (SNP) | VAF 23/23 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.429); catalogued as COSV64404504; called by muse, mutect2, varscan2
- ARL1 | c.312A>T p.K104N | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV55370552; called by muse, mutect2, varscan2
- ARMC9 | c.1081A>T p.I361F | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV63021902; called by muse, mutect2, varscan2
- BCAS1 | c.1508A>G p.K503R | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs372161022; called by muse, mutect2, varscan2
- BTBD16 | c.885T>A p.Y295* | Nonsense Mutation (SNP) | VAF 45/49 reads (92%) | catalogued as COSV53264253; called by muse, mutect2, varscan2
- C19orf54 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs780245332, COSV54573146; called by muse, mutect2, varscan2
- CDX2 | c.883T>C p.S295P | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV66829638; called by muse, mutect2, varscan2
- CEACAM5 | c.77C>A p.T26N | Missense Mutation (SNP) | VAF 73/208 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.55); catalogued as rs782259884, COSV55753032; called by muse, mutect2, varscan2
- CPSF6 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as rs775771978, COSV57015897; called by muse, mutect2, varscan2
- CTNNA1 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs758561244, COSV57072507; ClinVar: uncertain significance; called by muse, mutect2
- CYP4A11 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as rs202214253, COSV60224168; called by muse, mutect2, varscan2
- DMTF1 | c.725A>G p.H242R | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58686444, COSV58687206; called by muse, mutect2, varscan2
- DOCK8 | c.5179G>A p.G1727S | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs771636750, COSV66621239; called by muse, mutect2, varscan2
- FOXR2 | c.188G>C p.R63T | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100189468, COSV59258974, COSV59259767; called by muse, mutect2, varscan2
- GEM | c.409-1G>A p.X137_splice | Splice Site (SNP) | VAF 30/64 reads (47%) | catalogued as COSV52597896, COSV99891379; called by muse, mutect2, varscan2
- IL1A | c.381G>A p.M127I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV54519766; called by muse, mutect2, varscan2
- KNL1 | c.412T>G p.L138V (on ENST00000346991 / NM_170589.5; = p.L112V on NM_144508.5) | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61156693; called by muse, mutect2, varscan2
- KPNA5 | c.512C>G p.A171G | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV62651408, COSV62653082; called by muse, mutect2, varscan2
- MUC16 | c.10040G>A p.W3347* | Nonsense Mutation (SNP) | VAF 99/169 reads (59%) | catalogued as COSV67475885; called by muse, mutect2, varscan2
- NR1I3 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs372603248, COSV63468484; called by muse, mutect2, varscan2
- OR4C46 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as rs765272100, COSV60220066, COSV60220306; called by muse, mutect2, varscan2
- PCDHGA9 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.298); catalogued as COSV53917968; called by muse, mutect2, varscan2
- PDGFRA | c.862T>C p.Y288H | Missense Mutation (SNP) | VAF 82/156 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57270009; called by muse, mutect2, varscan2
- PIRT | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780812633, COSV74119911; called by muse, mutect2, varscan2
- PTK2B | c.1822G>A p.V608I | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs370995513; called by muse, mutect2, varscan2
- RAD54L2 | c.3205C>T p.Q1069* | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | catalogued as COSV56579542; called by muse, mutect2, varscan2
- RBM46 | c.824T>C p.F275S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55980007; called by muse, mutect2, varscan2
- SLC30A3 | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.23); catalogued as rs779046494, COSV51986292; called by muse, mutect2, varscan2
- TEP1 | c.6620C>T p.S2207L | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV52994902; called by muse, mutect2, varscan2
- UTRN | c.1051A>T p.T351S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150684617; called by muse, mutect2, varscan2
- ZFAT | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV64741026; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2095G>A p.D699N | Missense Mutation (SNP) | VAF 64/118 reads (54%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as rs148950715; called by muse, mutect2, varscan2
- FBN3 | c.1755_1756del p.H586Lfs*79 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | called by mutect2, pindel, varscan2
- TRBV4-1 | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- ADAMTS17 | c.2745C>T p.S915= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV51484873; called by muse, varscan2
- BTNL8 | c.1026C>T p.Y342= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV51459539; called by muse, mutect2, varscan2
- COL15A1 | c.1989G>A p.E663= | Silent (SNP) | VAF 14/20 reads (70%) | catalogued as COSV66642872; called by muse, mutect2, varscan2
- CYP2C18 | c.84G>A p.R28= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV53672329, COSV53673061; called by muse, mutect2, varscan2
- DOCK7 | c.3489G>T p.T1163= (on ENST00000635253 / NM_001367561.1; = p.T1132= on NM_033407.3) | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV52005184; called by muse, mutect2, varscan2
- HSPB3 | c.228C>T p.D76= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as rs761293721, COSV57356774, COSV57357254; called by muse, mutect2, varscan2
- LPCAT1 | c.483G>T p.P161= | Silent (SNP) | VAF 33/49 reads (67%) | catalogued as COSV52037263, COSV52039093; called by muse, mutect2, varscan2
- MUC5B | c.7536C>T p.P2512= | Silent (SNP) | VAF 43/73 reads (59%) | catalogued as rs527785289; called by muse, mutect2, varscan2
- NLRP12 | c.2031C>T p.R677= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs747097064, COSV60749691; called by muse, mutect2, varscan2
- SLC6A15 | c.1959A>T p.A653= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as rs750174715, COSV57025489; called by muse, mutect2, varscan2
- TXNIP | c.534G>A p.V178= | Silent (SNP) | VAF 82/291 reads (28%) | catalogued as rs1559266492, COSV65220722; called by muse, mutect2, varscan2
- VTCN1 | c.268C>T p.L90= | Silent (SNP) | VAF 73/141 reads (52%) | catalogued as COSV60224062; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73829203 A>G | 3'Flank (SNP) | VAF 14/31 reads (45%) | catalogued as rs1403323633; called by muse, mutect2, varscan2
- MAGEA5 | n.117G>A | RNA (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- MIR371A | n.48C>T | RNA (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
